Somatic mutation profile of tumor specimen 0DQHB6 from CCDI case PBCEYT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 0.9 years (311 days).
Specimen 0DQHB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 514766d6-aecd-4093-a893-5324f2d76875.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0776dde-22c8-4b8c-8baf-fecf0ab0bf76

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMG5 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 45/503 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs143050262; called by muse, mutect2
- CCDC80 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 192/456 reads (42%) | called by muse, mutect2, varscan2
- IQSEC2 | c.1228C>T p.P410S (on ENST00000642864 / NM_001111125.3; = p.P205S on NM_015075.2) | Missense Mutation (SNP) | VAF 82/600 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.67171G>A p.D22391N (on ENST00000591111; = p.D14967N on NM_003319.4) | Missense Mutation (SNP) | VAF 219/717 reads (31%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIPBL | c.4746A>G p.E1582= | Silent (SNP) | VAF 147/512 reads (29%) | called by muse, mutect2, varscan2
